Somatic mutation profile of tumor specimen TCGA-RD-A8N6-01A (aliquot TCGA-RD-A8N6-01A-11D-A364-08) from TCGA case TCGA-RD-A8N6, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 78.9 years (28,834 days).
Specimen TCGA-RD-A8N6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6252c47c-123f-4a4b-a635-e97ae2cd51a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RD-A8N6-10A (Blood Derived Normal), aliquot TCGA-RD-A8N6-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bb6be129-5cf2-4634-8085-6675e2b3b1da

The open-access MAF lists 171 somatic variants for this specimen: 126 protein-altering or splice-affecting, 41 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 95, Silent 41, Nonsense Mutation 12, Frame Shift Del 10, Frame Shift Ins 4, Splice Site 3, In Frame Del 2, Intron 1, 3'UTR 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL5A1 | c.2897del p.P966Lfs*108 | Frame Shift Del (DEL) | VAF 12/41 reads (29%) | catalogued as rs1179967153; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PYGM | c.1456G>A p.G486S | Missense Mutation (SNP) | VAF 30/292 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs926661627, COSV51216502; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.782+1G>A p.X261_splice | Splice Site (SNP) | VAF 19/21 reads (90%) | hotspot (GDC flag); catalogued as rs1555525429, COSV52665287, COSV52673806, COSV52698978; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ALDH6A1 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1339163343, COSV63247235; called by muse, mutect2, varscan2
- AMACR | c.288G>C p.Q96H | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.726); catalogued as COSV100163309; called by muse, mutect2, varscan2
- ANTXR1 | c.848C>A p.A283E | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100363270, COSV58010898; called by muse, mutect2, varscan2
- ATP2B4 | c.3233A>T p.E1078V | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as COSV100398140; called by muse, mutect2, varscan2
- AXIN2 | c.2078C>T p.T693M | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs755519590, COSV100197106, COSV61056581; ClinVar: uncertain significance; called by muse, varscan2
- CALHM1 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1328419907, COSV100324430; called by muse, mutect2, varscan2
- CBFA2T2 | c.1309T>A p.F437I | Missense Mutation (SNP) | VAF 21/214 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100656570; called by muse, mutect2
- CCBE1 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs199902030; called by muse, mutect2, varscan2
- CD163 | c.3415G>T p.G1139* | Nonsense Mutation (SNP) | VAF 8/64 reads (13%) | catalogued as COSV100776190; called by muse, mutect2, varscan2
- CES1 | c.1303C>T p.R435W (on ENST00000361503 / NM_001025194.2; = p.R434W on NM_001266.5) | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as rs376976316, COSV62085308; called by muse, mutect2, varscan2
- CHRNE | c.439G>A p.V147I | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as rs771950733, COSV53419220; called by muse, mutect2
- COL12A1 | c.8686G>A p.G2896R | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59389037; called by muse, mutect2, varscan2
- CRYBB3 | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs936212789, COSV99309226; called by muse, mutect2, varscan2
- CTNNA3 | c.2568dup p.P857Tfs*4 | Frame Shift Ins (INS) | VAF 14/70 reads (20%) | catalogued as rs759618368; called by mutect2, varscan2
- CUL9 | c.4635G>A p.M1545I | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1352165538, COSV99336190; called by muse, mutect2
- CYP2U1 | c.844G>C p.G282R | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as COSV100256863; called by muse, mutect2, varscan2
- DAB1 | c.218C>A p.A73D | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100141043; called by muse, mutect2, varscan2
- DCAF12L1 | c.383G>A p.G128D | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs373280004, COSV100948484; called by muse, mutect2, varscan2
- DDI2 | c.373A>G p.I125V | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100197936; called by muse, mutect2, varscan2
- DHX35 | c.483G>T p.M161I | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.038); catalogued as COSV99327434; called by muse, mutect2
- EIF2AK2 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs758776026, COSV99241098; called by muse, mutect2, varscan2
- ELANE | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1424691242; called by muse, mutect2, varscan2
- ELMOD1 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.072); catalogued as rs201382091; called by muse, mutect2, varscan2
- FLG | c.9836C>G p.A3279G | Missense Mutation (SNP) | VAF 93/543 reads (17%) | SIFT tolerated (1); PolyPhen possibly damaging (0.599); catalogued as COSV100912395; called by muse, mutect2, varscan2
- FMNL2 | c.2212C>T p.R738W | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs543308996, COSV99981172; called by muse, mutect2, varscan2
- FOXC2 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 25/68 reads (37%) | catalogued as CM013945, COSV100234432; called by muse, mutect2, varscan2
- FRK | c.11T>C p.I4T | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV74177375; called by muse, mutect2, varscan2
- FZD6 | c.539A>T p.Q180L | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV100708522; called by muse, mutect2, varscan2
- GABRR3 | c.480G>C p.E160D | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0.019); catalogued as COSV101512368; called by muse, mutect2, varscan2
- GALR1 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs1026231983, COSV55317434; called by muse, mutect2, varscan2
- GET3 | c.739G>A p.V247I | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as rs780011838, COSV62002977; called by muse, mutect2, varscan2
- GGT5 | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.93); PolyPhen benign (0.028); catalogued as rs374828667; called by muse, varscan2
- GINM1 | c.768G>A p.W256* | Nonsense Mutation (SNP) | VAF 22/125 reads (18%) | catalogued as rs1330120127, COSV100805388; called by muse, mutect2, varscan2
- GPHN | c.1354C>T p.R452W (on ENST00000315266 / NM_001377519.1; = p.R485W on NM_020806.5) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV59495321; called by muse, mutect2, varscan2
- GPR45 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs903481209, COSV51525098; called by muse, mutect2, varscan2
- GRM6 | c.1954G>A p.A652T | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.464); catalogued as rs150850494; called by muse, mutect2, varscan2
- HGS | c.107G>T p.R36L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs770624508, COSV100230527, COSV100230857; called by muse, mutect2, varscan2
- HPR | c.166T>A p.Y56N | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV99931079; called by muse, mutect2, varscan2
- IL16 | c.1474C>T p.R492* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as rs764346894, COSV100268315; called by muse, mutect2, varscan2
- ITGA11 | c.725C>T p.T242M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369764817; called by muse, varscan2
- KCTD19 | c.1336C>T p.R446* | Nonsense Mutation (SNP) | VAF 18/31 reads (58%) | catalogued as rs1033185025, COSV100431288; called by muse, mutect2, varscan2
- KDM5B | c.2819G>A p.R940H | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as rs368783569; called by muse, mutect2, varscan2
- LANCL2 | c.923C>G p.S308* | Nonsense Mutation (SNP) | VAF 8/114 reads (7%) | catalogued as COSV99635254; called by muse, mutect2
- LHCGR | c.1815A>C p.K605N | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54298497; called by muse, mutect2, varscan2
- LPCAT3 | c.1286G>C p.W429S | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV99781361; called by muse, mutect2, varscan2
- LRIT2 | c.101G>C p.S34T | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.045); catalogued as COSV100928360; called by muse, mutect2, varscan2
- LRRTM1 | c.1435C>T p.Q479* | Nonsense Mutation (SNP) | VAF 6/60 reads (10%) | catalogued as COSV99703362; called by mutect2, varscan2
- MACF1 | c.21215T>C p.F7072S (on ENST00000372915; = p.F5117S on NM_012090.5) | Missense Mutation (SNP) | VAF 78/157 reads (50%) | catalogued as COSV99247451; called by muse, mutect2, varscan2
- MAGEC1 | c.3283G>A p.V1095I | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as rs147835720, COSV53573381; called by muse, mutect2, varscan2
- MCOLN3 | c.364G>C p.V122L | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.997); catalogued as COSV100353097; called by muse, mutect2, varscan2
- MEIOB | c.814C>T p.R272* | Nonsense Mutation (SNP) | VAF 12/66 reads (18%) | catalogued as rs35694423; called by muse, mutect2, varscan2
- MEIS1 | c.1164C>G p.H388Q | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV99715915; called by muse, mutect2
- MELK | c.1822A>G p.T608A | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.145); catalogued as rs1289953901, COSV99975227; called by muse, mutect2, varscan2
- NASP | c.67G>C p.D23H | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.766); catalogued as COSV100602054, COSV99051979; called by muse, mutect2
- NCOA1 | c.2402T>G p.L801R | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV99947357; called by muse, mutect2, varscan2
- NIPBL | c.8377C>G p.R2793G | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as CM107662, COSV99243150; called by muse, mutect2, varscan2
- NPY2R | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as rs201784122, COSV100279983; called by muse, mutect2, varscan2
- OR10K1 | c.791C>T p.T264I | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as COSV99194069; called by muse, mutect2, varscan2
- OR52E2 | c.315dup p.I106Yfs*18 | Frame Shift Ins (INS) | VAF 6/17 reads (35%) | catalogued as rs1215131608; called by mutect2, pindel, varscan2
- OR7A5 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.75); catalogued as COSV100458014; called by muse, mutect2, varscan2
- P2RY10 | c.991A>T p.K331* | Nonsense Mutation (SNP) | VAF 30/71 reads (42%) | catalogued as COSV99409461; called by muse, mutect2, varscan2
- PCDH17 | c.1013C>T p.T338M | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.994); catalogued as COSV100932176; called by muse, mutect2, varscan2
- PHLDB2 | c.1507G>A p.D503N | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as rs1193876824, COSV101208780; called by muse, mutect2
- PHRF1 | c.2732C>A p.A911D (on ENST00000264555 / NM_001286581.2; = p.A910D on NM_020901.4) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.1); catalogued as COSV52754521; called by muse, mutect2, varscan2
- PLXNA4 | c.2892del p.M966Cfs*7 | Frame Shift Del (DEL) | VAF 15/146 reads (10%) | catalogued as COSV100328104; called by mutect2, pindel, varscan2
- PLXNC1 | c.4093C>A p.L1365I | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as COSV99314082; called by muse, mutect2, varscan2
- PRR35 | c.1564G>A p.D522N | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1022113785, COSV99216644; called by muse, mutect2, varscan2
- PTGER2 | c.1024A>T p.T342S | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as COSV99817818; called by muse, mutect2
- PTPN5 | c.1345C>T p.R449* | Nonsense Mutation (SNP) | VAF 37/82 reads (45%) | catalogued as rs769658239, COSV100080608; called by muse, mutect2, varscan2
- RAD23B | c.454C>G p.P152A | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.097); catalogued as COSV100787781; called by muse, mutect2, varscan2
- RARG | c.274G>A p.V92M | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV100553772; called by muse, mutect2, varscan2
- REST | c.308C>G p.P103R | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as rs751894476, COSV100471247, COSV100471430; called by muse, mutect2, varscan2
- RNF17 | c.3737G>A p.R1246H | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1358396060, COSV55040269; called by muse, mutect2, varscan2
- RNF214 | c.1993G>A p.V665I | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs772228026, COSV100326803; called by muse, mutect2, varscan2
- ROCK1 | c.2036C>G p.S679* | Nonsense Mutation (SNP) | VAF 6/66 reads (9%) | catalogued as COSV101296653; called by muse, mutect2
- RPS7 | c.476A>C p.D159A | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100513943, COSV100514031; called by muse, mutect2
- RTL9 | c.1303G>A p.G435R | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.66); catalogued as COSV101511819; called by muse, mutect2, varscan2
- SCN2B | c.44C>T p.T15M | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.081); catalogued as rs201373014, COSV54050539; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEC14L4 | c.1136A>G p.Y379C | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748825329, COSV99743428; called by muse, mutect2, varscan2
- SETD1A | c.1072C>G p.Q358E | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); catalogued as COSV52688490, COSV99353888; called by muse, mutect2, varscan2
- SH3BP4 | c.1630A>T p.N544Y | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV100749365; called by muse, mutect2, varscan2
- SLC13A5 | c.625A>G p.T209A | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.314); catalogued as COSV99546261; called by muse, mutect2, varscan2
- SLC26A6 | c.601A>T p.I201F | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as COSV99375370; called by muse, mutect2, varscan2
- SLC45A1 | c.1097C>T p.S366L | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1188506306, COSV99239795; called by muse, mutect2, varscan2
- SLU7 | c.1067C>G p.S356C | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99775873; called by muse, mutect2, varscan2
- SORCS1 | c.1004A>C p.E335A | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99551157; called by muse, mutect2, varscan2
- STK24 | c.185T>C p.V62A | Missense Mutation (SNP) | VAF 174/347 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100925052; called by muse, mutect2, varscan2
- TBL1X | c.416T>C p.M139T | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0.15); catalogued as COSV99483309; called by muse, mutect2, varscan2
- TCTN2 | c.896C>G p.S299C | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100315439; called by muse, mutect2, varscan2
- TFDP3 | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1363372407, COSV100033604; called by muse, mutect2
- TGIF2LX | c.425T>C p.V142A | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.185); catalogued as rs773755289, COSV99383570; called by muse, mutect2, varscan2
- THSD7A | c.1823G>C p.G608A | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as COSV101448957; called by muse, mutect2, varscan2
- TMC6 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1346749221, COSV100130447; called by muse, mutect2, varscan2
- TNC | c.5026G>A p.D1676N | Missense Mutation (SNP) | VAF 7/143 reads (5%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.646); catalogued as COSV100406448; called by muse, mutect2
- TRIB1 | c.1009T>C p.W337R | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100322635, COSV61335560; called by muse, mutect2, varscan2
- TTC3 | c.5950A>T p.K1984* | Nonsense Mutation (SNP) | VAF 21/77 reads (27%) | catalogued as COSV100696159; called by muse, mutect2, varscan2
- TTN | c.38746G>A p.D12916N (on ENST00000591111; = p.D5492N on NM_003319.4) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | PolyPhen benign (0.003); catalogued as rs794729431, COSV60181732; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UGT1A1 | c.1079T>C p.L360P | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100531262; called by muse, mutect2
- UPK1A | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.848); catalogued as rs577633517, COSV99722112; called by muse, mutect2, varscan2
- USP26 | c.1461del p.F487Lfs*40 | Frame Shift Del (DEL) | VAF 32/118 reads (27%) | catalogued as rs761320003; called by mutect2, varscan2
- VAV1 | c.65G>T p.R22L | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100409562; called by muse, mutect2, varscan2
- VPS13D | c.7131G>T p.Q2377H | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99170060; called by muse, mutect2, varscan2
- ZDHHC14 | c.712C>A p.Q238K | Missense Mutation (SNP) | VAF 70/361 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0.017); catalogued as COSV100399488; called by muse, mutect2, varscan2
- ZIC4 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1332082789, COSV67172905; called by muse, mutect2, varscan2
- ZIM3 | c.743A>G p.E248G | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99518849; called by muse, mutect2, varscan2
- ZNF208 | c.2008T>A p.C670S | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101237264; called by muse, mutect2, varscan2
- ZNF341 | c.1623-2A>G p.X541_splice (on ENST00000375200 / NM_001282935.1; = p.X534_splice on NM_032819.4) | Splice Site (SNP) | VAF 66/233 reads (28%) | catalogued as COSV100678171; called by muse, mutect2, varscan2
- ZNF408 | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs775347285, COSV100305726; called by muse, mutect2, varscan2
- ZNF623 | c.1501A>G p.N501D | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV101513623; called by muse, mutect2, varscan2
- ZNF71 | c.71del p.G24Dfs*45 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | catalogued as COSV60146904; called by mutect2, pindel
- ABCD2 | c.10_11del p.M4Afs*6 | Frame Shift Del (DEL) | VAF 10/37 reads (27%) | called by pindel, varscan2
- ABL2 | c.2386del p.R796Gfs*4 (on ENST00000502732 / NM_007314.4; = p.R781Gfs*4 on NM_005158.5) | Frame Shift Del (DEL) | VAF 14/79 reads (18%) | called by mutect2, pindel, varscan2
- CDCA8 | c.665_667del p.A222del | In Frame Del (DEL) | VAF 9/50 reads (18%) | called by mutect2, pindel, varscan2
- CSPG4 | c.764T>C p.I255T | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- DOCK7 | c.1678del p.Y560Tfs*24 | Frame Shift Del (DEL) | VAF 13/69 reads (19%) | called by mutect2, pindel, varscan2
- DUSP9 | c.1005dup p.Q336Afs*6 | Frame Shift Ins (INS) | VAF 28/173 reads (16%) | called by pindel, varscan2
- FAT3 | c.9646dup p.L3216Pfs*15 | Frame Shift Ins (INS) | VAF 6/22 reads (27%) | called by mutect2, pindel, varscan2
- GFRA3 | c.379_379+13del p.X127_splice | Splice Site (DEL) | VAF 9/35 reads (26%) | called by mutect2, pindel, varscan2
- IARS2 | c.676A>C p.T226P | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.342); called by muse, varscan2
- IARS2 | c.683_684del p.Y228Sfs*4 | Frame Shift Del (DEL) | VAF 18/126 reads (14%) | called by pindel, varscan2
- PYGM | c.1688_1692del p.L563Rfs*11 | Frame Shift Del (DEL) | VAF 18/90 reads (20%) | called by mutect2, pindel, varscan2
- TFCP2 | c.1300_1302del p.E434del | In Frame Del (DEL) | VAF 8/36 reads (22%) | called by pindel, varscan2
- ZNF233 | c.1290_1293del p.S431Tfs*274 | Frame Shift Del (DEL) | VAF 16/67 reads (24%) | called by pindel, varscan2
- ACP4 | c.366G>A p.G122= | Silent (SNP) | VAF 33/50 reads (66%) | catalogued as rs1161308048, COSV99567912; called by muse, mutect2, varscan2
- ATP7B | c.2326C>T p.L776= | Silent (SNP) | VAF 34/78 reads (44%) | catalogued as CM952199, COSV99667048; called by muse, mutect2, varscan2
- CACNA1C | c.3681C>T p.V1227= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as rs886049204, COSV100223370; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHST1 | c.612C>T p.A204= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as rs1216054152, COSV100346585; called by muse, mutect2, varscan2
- CILK1 | c.237C>T p.F79= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs754954751, COSV100608104; called by muse, mutect2, varscan2
- COL6A5 | c.6513G>A p.P2171= (on ENST00000312481; = p.P2167= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as rs750306317, COSV55202663; called by muse, mutect2, varscan2
- DACT1 | c.639C>G p.L213= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV100241645, COSV100242179; called by muse, mutect2
- DLL4 | c.1551C>T p.C517= | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as rs990283280, COSV99990034; called by muse, mutect2, varscan2
- DNAH8 | c.4005C>G p.L1335= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV100547445; called by muse, mutect2
- FBN1 | c.6303G>A p.T2101= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV57311233; called by muse, mutect2, varscan2
- HERC2 | c.7950T>C p.S2650= | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as COSV99877526; called by muse, mutect2, varscan2
- HFM1 | c.2199T>C p.S733= | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as COSV99647045; called by muse, mutect2, varscan2
- HTR3C | c.408G>A p.T136= | Silent (SNP) | VAF 36/119 reads (30%) | catalogued as rs375164093; called by muse, mutect2, varscan2
- KHDRBS3 | c.864T>C p.D288= | Silent (SNP) | VAF 14/101 reads (14%) | catalogued as COSV100879116, COSV63422624; called by muse, mutect2, varscan2
- LPO | c.1803C>T p.Y601= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as rs141238819, COSV99228493; called by muse, mutect2, varscan2
- MMP2 | c.855C>T p.N285= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs760006274, COSV54599856, COSV54601302; called by mutect2, varscan2
- MMP25 | c.642C>G p.T214= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV100339663; called by muse, mutect2, varscan2
- NOTCH1 | c.6384G>A p.P2128= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs746762310, COSV53052924; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR4B1 | c.822G>A p.T274= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as rs775405091, COSV100535763; called by muse, mutect2, varscan2
- OR4C6 | c.190T>C p.L64= | Silent (SNP) | VAF 37/85 reads (44%) | catalogued as COSV58605224, COSV58606549; called by muse, mutect2, varscan2
- OR8H2 | c.516C>T p.N172= | Silent (SNP) | VAF 36/166 reads (22%) | catalogued as rs763293702, COSV57944151; called by muse, mutect2, varscan2
- OR8U1 | c.762C>A p.T254= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as rs376456406; called by muse, varscan2
- PCSK7 | c.78C>T p.A26= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs746175854, COSV100309582; called by muse, varscan2
- PJA2 | c.1974A>G p.K658= | Silent (SNP) | VAF 16/22 reads (73%) | catalogued as COSV100754577; called by muse, mutect2, varscan2
- PRKG2 | c.1512C>A p.I504= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as rs1167261893, COSV100020707; called by muse, mutect2, varscan2
- PTPA | c.546G>A p.T182= (on ENST00000337738 / NM_178001.2; = p.T147= on NM_021131.5) | Silent (SNP) | VAF 26/118 reads (22%) | catalogued as rs746005579, COSV100534177; called by muse, mutect2, varscan2
- RPN2 | c.1686G>C p.R562= | Silent (SNP) | VAF 9/89 reads (10%) | catalogued as COSV99412168; called by muse, mutect2, varscan2
- SLITRK5 | c.141C>T p.I47= | Silent (SNP) | VAF 71/141 reads (50%) | catalogued as COSV100280925, COSV61523495; called by muse, mutect2, varscan2
- SUPT6H | c.4836G>A p.V1612= | Silent (SNP) | VAF 8/214 reads (4%) | catalogued as COSV99973199; called by muse, mutect2
- THSD7B | c.1281G>A p.T427= | Silent (SNP) | VAF 22/27 reads (81%) | catalogued as rs563732139, COSV55693111, COSV99760095; called by muse, mutect2, varscan2
- TMEM132D | c.1311C>T p.I437= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV70599498; called by muse, mutect2, varscan2
- TTN | c.50937A>G p.A16979= (on ENST00000591111; = p.A9555= on NM_003319.4) | Silent (SNP) | VAF 35/123 reads (28%) | catalogued as COSV100634783; called by muse, mutect2, varscan2
- TTN | c.44472C>T p.D14824= (on ENST00000591111; = p.D7400= on NM_003319.4) | Silent (SNP) | VAF 65/141 reads (46%) | catalogued as rs749308557, COSV60380013; ClinVar: uncertain significance / likely benign / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- TTN | c.3318C>T p.G1106= (on ENST00000591111; = p.G1060= on NM_003319.4) | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as rs141768043; ClinVar: uncertain significance / likely benign / benign; called by muse, mutect2, varscan2
- VSTM4 | c.204C>T p.F68= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs760502568, COSV53679134; called by muse, mutect2, varscan2
- ZCWPW2 | c.879A>G p.G293= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs1273814815, COSV101075436; called by muse, mutect2, varscan2
- ZNF117 | c.339A>G p.E113= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs201978453, COSV99276248; called by muse, mutect2, varscan2
- ZNF300 | c.1299T>C p.G433= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as COSV99200427; called by muse, mutect2, varscan2
- ZNF561 | c.630A>C p.A210= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV100254826; called by muse, mutect2, varscan2
- ZNF610 | c.639T>C p.F213= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100017089; called by muse, mutect2, varscan2
- ZNF85 | c.789T>C p.C263= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs1369264050, COSV100060208; called by muse, mutect2
- ATAD3B | c.325-21C>T | Intron (SNP) | VAF 4/34 reads (12%) | catalogued as rs1171509566, COSV100426685; called by muse, mutect2
- MFSD4B | c.*879G>T | 3'UTR (SNP) | VAF 7/42 reads (17%) | catalogued as COSV100920620; called by muse, mutect2, varscan2
- PPIA | c.-2C>T | 5'UTR (SNP) | VAF 14/112 reads (13%) | catalogued as rs1269764517, COSV100587853; called by muse, varscan2
- WBP1LP2 | n.276G>A | RNA (SNP) | VAF 12/66 reads (18%) | called by muse, mutect2, varscan2
